Gene-level copy-number profile of tumor specimen TCGA-D8-A1JP-01A from TCGA case TCGA-D8-A1JP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.5 years (26,862 days).
Specimen TCGA-D8-A1JP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1dd196c1-6198-4edf-b8a1-66fed90a68b3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2b68f449-b978-4c33-8237-c8e801049aed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 16; copy number 2: 14,589; copy number 3: 4,189; copy number 4: 30,395; copy number 5: 2,159; copy number 6: 3,325; copy number 7: 721; copy number 8: 1,622; copy number 9: 400; copy number 10: 1,046; copy number 11: 599; copy number 12: 443; copy number 13: 246; copy number 16: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JP-01A-11D-A13J-01): tumor purity 0.68, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:22,381,819–22,382,929, 1 gene: HMGB1P5.
- chr16:77,104,260–79,827,150, 54 genes: AC106733.1, MON1B, SYCE1L, AC009139.2, VN2R10P, AC009139.1, ADAMTS18, AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, AC092134.3, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2, WWOX, AC079414.3, AC009044.1, WWOX-AS1, AC106743.1, LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1, RNA5SP431, AC084064.1, MAF, AC009159.2, AC009159.3, AC009159.1, AC009159.4, LINC01229, MAFTRR, LINC01228.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,742 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,261,741–192,957,713, 633 genes, copy number 11–13 (within-gene range 8–13) (broad region; genes not listed).
- chr1:198,450,666–205,684,307, 205 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr6:88,378,280–131,951,372, 530 genes, copy number 9–10 (broad region; genes not listed).
- chr7:29,806,486–35,379,675, 101 genes, copy number 9 (broad region; genes not listed).
- chr8:58,805,412–59,119,147, 1 gene, copy number 10 (within-gene range 5–10): TOX.
- chr8:58,991,720–120,542,133, 880 genes, copy number 10–12 (within-gene range 8–12) (broad region; genes not listed).
- chr8:124,539,101–132,013,642, 97 genes, copy number 10 (broad region; genes not listed).
- chr12:68,842,197–74,402,600, 80 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr12:80,763,151–83,134,870, 24 genes, copy number 9–11 (within-gene range 4–11): LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P.
- chr22:28,742,039–34,218,796, 191 genes, copy number 9–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
